MMRF case MMRF_2848 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c1906ef6-a672-4688-a80d-4734f8203c0e

Demographics
Sex at birth: female; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; ISS stage: II; Days to last known disease status: 198 days; Days to last follow up: 198 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 200 days; Days to treatment end: 200 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -6, day 198.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Creatinine 190 µmol/L.
- Calcium 2.5 mmol/L.
- Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL.
- Albumin 30.5 g/L.
- Beta 2 Microglobulin 5.3 µg/mL.
- Absolute Neutrophil 16.2 ×10⁹/L.
- Lactate Dehydrogenase 2.1 µkat/L.
- Serum Free Immunoglobulin Light Chain, Lambda 314 mg/dL.
- M Protein 5.31 g/dL.
- Hemoglobin 4.9 mmol/L.
- Platelets 290 ×10⁹/L.

Other clinical attributes
- Day -6: Weight: 67 kg; Height: 0 cm.

Biospecimens (2 samples)
- Sample MMRF_2848_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2848_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
